Somatic mutation profile of tumor specimen TCGA-KL-8337-01A (aliquot TCGA-KL-8337-01A-11D-2310-10) from TCGA case TCGA-KL-8337, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 26.9 years (9,819 days).
Specimen TCGA-KL-8337-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6296c03-fc97-4c9b-8b13-2d62bd9c290d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8337-11A (Solid Tissue Normal), aliquot TCGA-KL-8337-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/692d8051-f3de-401e-a424-2f3c6820ad2a

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 2, Intron 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 4/50 reads (8%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2
- ATMIN | c.1524G>A p.M508I | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100214637; called by muse, mutect2, varscan2
- C2orf78 | c.2299C>A p.P767T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as COSV101280980, COSV68518967; called by muse, mutect2
- CNOT2 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV99972676; called by muse, mutect2
- DCST2 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99791978; called by muse, mutect2, varscan2
- KIF7 | c.3374A>G p.E1125G | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV99176570; called by muse, mutect2
- NLRP11 | c.326A>C p.E109A | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV100789755; called by muse, mutect2, varscan2
- OR6F1 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs145498993, COSV57467006; called by muse, mutect2, varscan2
- PKM | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100064876; called by muse, mutect2
- RGS16 | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100842488, COSV62375956; called by muse, varscan2
- SPRR3 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs139991128; called by muse, varscan2
- SPTA1 | c.1355A>G p.E452G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100935075; called by muse, mutect2, varscan2
- SRRM2 | c.3122C>A p.S1041Y | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV100070909; called by muse, mutect2, varscan2
- TBCC | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1395048613, COSV99773973; called by muse, mutect2, varscan2
- TMEM108 | c.869C>A p.T290N | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100418985, COSV58885911; called by muse, mutect2, varscan2
- AREG | c.448T>G p.F150V | Missense Mutation (SNP) | VAF 25/814 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- AC132217.2 | c.327G>A p.S109= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs754199654, COSV100324083; called by muse, mutect2, varscan2
- CTDP1 | c.2829C>T p.S943= | Silent (SNP) | VAF 45/222 reads (20%) | catalogued as rs1221580888, COSV50005577; called by muse, varscan2
- SPRY3 | c.*947G>A | 3'UTR (SNP) | VAF 102/477 reads (21%) | catalogued as COSV100249372; called by muse, mutect2, varscan2
- TTLL11 | c.1539+39G>A | Intron (SNP) | VAF 17/61 reads (28%) | catalogued as rs1207808512, COSV100388861; called by muse, mutect2, varscan2
